Somatic mutation profile of tumor specimen TARGET-20-PATHIW-09A (aliquot TARGET-20-PATHIW-09A-01D) from TARGET case TARGET-20-PATHIW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,750 days).
Specimen TARGET-20-PATHIW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10c015a8-6b38-4ea7-b295-cf8046a798a8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATHIW-14A (Bone Marrow Normal), aliquot TARGET-20-PATHIW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b7f6357-e2ed-47fb-a8f7-6e6090ccf075

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.755G>A p.W252* (on ENST00000344691 / NM_001001890.3; = p.W279* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 62/152 reads (41%) | catalogued as CM161062; called by muse, mutect2, varscan2
- BSN | c.3554A>C p.E1185A | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC8 | c.*155T>A | 3'UTR (SNP) | VAF 43/72 reads (60%) | called by muse, mutect2, varscan2
- PPP2R3B | c.793-31C>T | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs780967487; called by muse, mutect2, varscan2
